Somatic mutation profile of tumor specimen TCGA-G4-6625-01A (aliquot TCGA-G4-6625-01A-21D-1771-10) from TCGA case TCGA-G4-6625, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 77.1 years (28,163 days).
Specimen TCGA-G4-6625-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77fefc2e-134e-4a15-9e54-309d4b338e64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6625-11A (Solid Tissue Normal), aliquot TCGA-G4-6625-11A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cfaeda5-6792-48c3-bde8-62f0f382a2e8

The open-access MAF lists 117 somatic variants for this specimen: 90 protein-altering or splice-affecting, 27 silent.
By variant classification: Missense Mutation 73, Silent 27, Nonsense Mutation 8, Splice Region 3, Frame Shift Ins 3, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3980C>G p.S1327* | Nonsense Mutation (SNP) | VAF 26/75 reads (35%) | catalogued as rs1554085429, COSV57323640, COSV57335489, COSV57371230; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 27/131 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.2236T>G p.C746G (on ENST00000404938 / NM_001163941.2; = p.C301G on NM_178559.6) | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV99329436; called by muse, mutect2
- AFF3 | c.2839C>T p.R947W | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as rs756186388, COSV57881189; called by muse, mutect2, varscan2
- ANO6 | c.1709C>G p.A570G | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100263840; called by muse, mutect2, varscan2
- ATP1A2 | c.2266G>A p.V756I | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs777895941, COSV63403252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP4A | c.2656C>A p.Q886K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV52867076; called by muse, mutect2, varscan2
- BRWD3 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 99/279 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV64746517; called by muse, mutect2, varscan2
- C22orf23 | c.481C>T p.L161= | Splice Region (SNP) | VAF 26/177 reads (15%) | catalogued as rs1443045334, COSV50777758; called by muse, mutect2, varscan2
- CACNA1F | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV59903921; called by muse, mutect2, varscan2
- CACNA1H | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs369630836; called by muse, mutect2, varscan2
- CCDC173 | c.1351C>T p.Q451* | Nonsense Mutation (SNP) | VAF 12/222 reads (5%) | catalogued as COSV99644896; called by muse, mutect2
- CD58 | c.222C>G p.F74L | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV65664737; called by muse, mutect2, varscan2
- CDC20B | c.409A>T p.N137Y | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV57051242; called by muse, mutect2, varscan2
- CEP63 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59675442; called by muse, mutect2, varscan2
- CFAP157 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as rs773275895, COSV58852615; called by mutect2, varscan2
- CNMD | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 13/247 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65032778; called by muse, mutect2
- COL27A1 | c.1872G>T p.M624I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV61924540; called by muse, mutect2, varscan2
- COL3A1 | c.2557C>A p.P853T | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV58582247, COSV58585418; called by muse, mutect2, varscan2
- COX11 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV54802732; called by muse, mutect2, varscan2
- CREBBP | c.2159G>T p.G720V | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99271788; called by muse, mutect2, varscan2
- CTSC | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV57057223; called by muse, mutect2, varscan2
- CYP2F1 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as rs371341517; called by mutect2, varscan2
- DDX49 | c.1096C>A p.Q366K | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV99651233; called by muse, mutect2, varscan2
- DLGAP1 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100233389; called by muse, mutect2, varscan2
- DNAH7 | c.8369C>A p.A2790D | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100417291; called by muse, mutect2, varscan2
- DOLK | c.1315G>A p.V439I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.057); catalogued as rs372057636; called by muse, mutect2
- DSCAML1 | c.6079G>A p.A2027T (on ENST00000321322; = p.A1967T on NM_020693.4) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs776542181, COSV58387504; called by muse, varscan2
- EVPL | c.1539T>G p.A513= | Splice Region (SNP) | VAF 39/108 reads (36%) | catalogued as COSV101648799; called by muse, mutect2, varscan2
- EXOC1 | c.611T>A p.I204N | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62119837; called by muse, mutect2, varscan2
- FOLR3 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.596); catalogued as COSV100281863; called by muse, mutect2, varscan2
- GABRQ | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs782766146, COSV64780696; called by muse, mutect2, varscan2
- GDF9 | c.953G>T p.R318L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV51526052, COSV51526059; called by muse, mutect2, varscan2
- GMCL1 | c.1541dup p.N515Efs*22 | Frame Shift Ins (INS) | VAF 22/105 reads (21%) | catalogued as rs1282897493; called by mutect2, varscan2
- GPC3 | c.1143A>T p.E381D | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV100893530; called by muse, mutect2
- IL21R | c.905A>G p.E302G | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV61969555; called by muse, mutect2, varscan2
- IMP4 | c.324C>G p.F108L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as rs974372863, COSV52091524, COSV52091684; called by muse, mutect2, varscan2
- IQUB | c.31C>G p.Q11E | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV61238486, COSV61239806; called by muse, mutect2, varscan2
- JPH3 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1175751229, COSV52466364; called by muse, mutect2, varscan2
- KAT6A | c.5245G>A p.A1749T | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV55904969; called by muse, mutect2, varscan2
- KCNJ8 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 25/123 reads (20%) | catalogued as COSV99557552; called by muse, mutect2, varscan2
- KREMEN1 | c.446G>C p.S149T (on ENST00000407188; = p.S151T on NM_032045.5) | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.047); catalogued as COSV100588805; called by muse, mutect2, varscan2
- KSR2 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV60372361, COSV60382530; called by muse, mutect2, varscan2
- LRRC66 | c.985C>G p.H329D | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1468382370, COSV100603084; called by muse, mutect2, varscan2
- MAP7D3 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 204/712 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750357677, COSV60170568; called by muse, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | catalogued as rs750092100; called by mutect2, varscan2
- MGAT3 | c.1399G>A p.G467S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as rs376388006; called by muse, mutect2, varscan2
- MIDEAS | c.2044G>C p.A682P | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.896); catalogued as COSV99679200; called by muse, mutect2, varscan2
- MORC3 | c.608+1G>A p.X203_splice | Splice Site (SNP) | VAF 9/62 reads (15%) | catalogued as COSV101265044; called by muse, mutect2, varscan2
- MUC16 | c.15528G>C p.E5176D | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.329); catalogued as COSV67458124; called by muse, mutect2
- MYO1A | c.2570A>G p.K857R | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.093); catalogued as COSV55653103; called by muse, mutect2, varscan2
- NAV3 | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57072868, COSV57104963; called by muse, mutect2, varscan2
- NFATC2 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.402); catalogued as rs760093998, COSV65354707; called by muse, mutect2, varscan2
- NFRKB | c.725C>T p.T242M (on ENST00000446488 / NM_001143835.2; = p.T267M on NM_006165.3) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs147580505; called by muse, mutect2, varscan2
- NPM2 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs756290241, COSV57075464; called by muse, mutect2, varscan2
- OBSCN | c.2515C>G p.H839D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV99483814; called by muse, mutect2
- OR4D2 | c.423G>A p.W141* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV73459740; called by muse, mutect2, varscan2
- P2RX7 | c.1730T>C p.I577T | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99947760; called by muse, mutect2
- PCDH7 | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as rs1298790860; called by muse, mutect2, varscan2
- PLTP | c.857T>G p.L286R | Missense Mutation (SNP) | VAF 16/231 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100819125; called by muse, mutect2
- PPP3CB | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs1173573690, COSV100646262; called by muse, mutect2, varscan2
- RFX5 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1557830458, COSV99303292; called by muse, mutect2, varscan2
- RHOT1 | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.067); catalogued as rs1287847319, COSV61715356; called by muse, varscan2
- RIMS1 | c.1948C>A p.L650I | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99330131; called by muse, mutect2, varscan2
- RORB | c.203C>T p.T68M (on ENST00000396204 / NM_001365023.1; = p.T57M on NM_006914.4) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs779534868, COSV65334845; called by muse, mutect2, varscan2
- RTTN | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs745392772, COSV55343414; called by muse, mutect2, varscan2
- RUBCNL | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.129); catalogued as COSV59787146; called by muse, mutect2, varscan2
- RYR3 | c.10814A>C p.E3605A (on ENST00000389232; = p.E3606A on NM_001036.6) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV101214286; called by muse, mutect2
- SH3GLB1 | c.1094A>G p.N365S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1248562743, COSV65279530; called by muse, mutect2, varscan2
- SMARCAD1 | c.82T>G p.S28A | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as COSV100759031; called by muse, mutect2, varscan2
- SNX33 | c.371G>A p.C124Y | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.037); catalogued as COSV57913165; called by muse, mutect2, varscan2
- SP140L | c.800A>C p.K267T | Missense Mutation (SNP) | VAF 75/200 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.173); catalogued as COSV54742638; called by muse, mutect2, varscan2
- SYCP2 | c.3948dup p.L1317Tfs*3 | Frame Shift Ins (INS) | VAF 97/240 reads (40%) | catalogued as rs755832373; called by mutect2, pindel, varscan2
- SYT12 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as rs1015645623, COSV67355527; called by muse, mutect2, varscan2
- TGFBR1 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.028); catalogued as rs1368326650, COSV66625539; called by muse, mutect2
- TRIM45 | c.1470C>A p.G490= | Splice Region (SNP) | VAF 21/47 reads (45%) | catalogued as COSV56713294; called by muse, mutect2, varscan2
- TRO | c.3773G>C p.G1258A | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV99437225; called by muse, mutect2, varscan2
- UGT2B4 | c.1532G>C p.C511S | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV59315670, COSV59316413; called by muse, mutect2, varscan2
- VPS41 | c.1083C>A p.D361E | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV100054295; called by muse, mutect2, varscan2
- VWF | c.6652C>T p.R2218W | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs200382972, COSV54616473, COSV99778987; called by muse, mutect2, varscan2
- ZNF181 | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV101106439; called by muse, mutect2
- ZNF543 | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as rs747060594, COSV58627059; called by muse, mutect2, varscan2
- CUL4B | c.2371_2373delinsGG p.R791Gfs*31 | Frame Shift Del (DEL) | VAF 16/135 reads (12%) | called by pindel, varscan2*
- FAM83B | c.1459dup p.T487Nfs*8 | Frame Shift Ins (INS) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- GPR179 | c.3442T>C p.S1148P (on ENST00000621958; = p.S1147P on NM_001004334.4) | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GRIA3 | c.28A>G p.S10G | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2
- POLH | c.1651T>C p.S551P | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SYNE2 | c.8704T>C p.Y2902H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.135); called by muse, mutect2
- ZBTB40 | c.3514C>T p.Q1172* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- ADAMTSL4 | c.2517G>T p.G839= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV54998568, COSV99646470; called by muse, mutect2, varscan2
- ARHGAP4 | c.723G>A p.K241= | Silent (SNP) | VAF 14/139 reads (10%) | catalogued as COSV100604222; called by muse, mutect2
- BEND2 | c.1188C>G p.G396= | Silent (SNP) | VAF 31/266 reads (12%) | catalogued as COSV66215217, COSV66215543; called by muse, mutect2, varscan2
- CBX8 | c.657C>T p.S219= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as rs150395239; called by muse, mutect2, varscan2
- CC2D1A | c.2649C>A p.I883= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV54308386; called by muse, mutect2, varscan2
- CCM2 | c.486G>T p.G162= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV99348080; called by muse, varscan2
- CDH4 | c.2445C>T p.G815= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as rs762550906, COSV64649102; called by muse, mutect2, varscan2
- CDK14 | c.768C>T p.D256= (on ENST00000380050 / NM_001287135.2; = p.D238= on NM_012395.3) | Silent (SNP) | VAF 22/165 reads (13%) | catalogued as COSV56030663; called by muse, mutect2, varscan2
- DST | c.5553C>A p.V1851= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99759553; called by muse, mutect2, varscan2
- FBLN1 | c.1455C>T p.C485= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs1131172, COSV53045744; called by muse, mutect2, varscan2
- FOXC1 | c.513G>A p.R171= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as COSV66515828; called by muse, mutect2, varscan2
- GARRE1 | c.2229G>A p.P743= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs376976421; called by muse, mutect2, varscan2
- HTR1E | c.90G>C p.V30= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV100541281; called by muse, mutect2
- IRX1 | c.312G>T p.V104= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV57358810; called by muse, mutect2, varscan2
- IRX1 | c.543G>A p.A181= | Silent (SNP) | VAF 33/120 reads (28%) | catalogued as COSV57358819; called by muse, mutect2, varscan2
- KNDC1 | c.276C>T p.N92= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs757429553, COSV58834736; called by muse, mutect2, varscan2
- KRT25 | c.867C>T p.V289= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV56443988; called by muse, mutect2, varscan2
- LGI4 | c.756C>T p.Y252= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs1214783044, COSV59533168; called by muse, mutect2, varscan2
- MYH7 | c.5013C>T p.I1671= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs779978846, COSV62518142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OXTR | c.1134C>T p.S378= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs746072418, COSV57478939; called by muse, mutect2, varscan2
- PCLO | c.11652T>A p.P3884= | Silent (SNP) | VAF 18/202 reads (9%) | catalogued as COSV61626775; called by muse, mutect2
- PNCK | c.942G>T p.G314= (on ENST00000340888 / NM_001366975.1; = p.G397= on NM_001039582.3) | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV61743211, COSV61743284; called by muse, mutect2, varscan2
- PWWP3B | c.1125C>T p.D375= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as rs367590084, COSV61799131; called by muse, mutect2, varscan2
- SCN5A | c.1902G>A p.S634= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs764360705, COSV61120944; ClinVar: likely benign; called by muse, mutect2, varscan2
- SERPINA6 | c.129C>T p.N43= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs749109208, COSV58584336; called by muse, mutect2, varscan2
- SPAG16 | c.1842C>T p.D614= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs765928542, COSV56967112; called by muse, mutect2, varscan2
- ZIC3 | c.702C>T p.H234= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1278715154, COSV54972365; called by muse, mutect2, varscan2
